Gene-level copy-number profile of tumor specimen TCGA-JW-A852-01A from TCGA case TCGA-JW-A852, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 42.9 years (15,682 days).
Specimen TCGA-JW-A852-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.68708798-0dcb-402b-bf89-bea09cf548f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JW-A852-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/511dac5c-a6c1-4ed7-927b-5fe003cd0018

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 618; copy number 2: 50,178; copy number 3: 8,248; copy number 4: 73; copy number 6: 35; copy number 7: 1; copy number 8: 12; copy number 10: 7; copy number 11: 268; copy number 12: 360; copy number 13: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JW-A852-01A-11D-A350-01): tumor purity 0.81, ploidy 2.22, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 696 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:161,600,438–198,222,513, 646 genes, copy number 10–13 (within-gene range 3–13) (broad region; genes not listed).
- chr19:3,094,362–3,761,692, 35 genes, copy number 6 (within-gene range 3–6): GNA11, AC005262.2, KF456478.1, AC005262.1, GNA15, AC005264.1, S1PR4, NCLN, CELF5, AC010649.1, NFIC, AC007792.1, AC005514.1, SMIM24, AC005551.1, DOHH, FZR1, AC005787.1, MFSD12, C19orf71, AC005786.3, AC005786.2, AC005786.4, AC005786.1, HMG20B, GIPC3, TBXA2R, CACTIN-AS1, CACTIN, PIP5K1C, AC004637.1, TJP3, APBA3, AC005954.2, AC005954.1.
- chr22:40,043,068–40,682,814, 15 genes, copy number 7–11: Z83847.1, TNRC6B, RPL7P52, ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1.

Autosomal genes at a single copy (total copy number 1): 618. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
